Gene-level copy-number profile of tumor specimen TCGA-23-1114-01B from TCGA case TCGA-23-1114, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.9 years (20,409 days).
Specimen TCGA-23-1114-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0f187781-18d6-4a79-8d57-e0076abf1440.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1114-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2751bb8-e70e-4ac7-bd79-824c4c79f2ea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 432; copy number 2: 6,053; copy number 3: 20,584; copy number 4: 9,094; copy number 5: 11,357; copy number 6: 7,857; copy number 7: 3,006; copy number 8: 1,063; copy number 9: 74; copy number 11: 32; copy number 14: 68; copy number 21: 17; copy number 28: 45; copy number 31: 81; copy number 38: 4; copy number 46: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1114-01B-01D-0559-01): tumor purity 0.76, ploidy 4.19, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,443 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:81,080,790–89,936,611, 137 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr2:2,638,178–5,314,134, 35 genes, copy number 8: AC018685.2, AC018685.3, AC011995.2, AC018685.1, AC011995.1, LINC01250, AC019118.2, AC019118.1, EIPR1, EIPR1-IT1, TRAPPC12, TRAPPC12-AS1, AC114810.1, ADI1, AC231981.1, AC108488.1, AC108488.2, RNASEH1, RNASEH1-AS1, AC108488.3, RPS7, COLEC11, AC010907.2, TMSB4XP2, ALLC, GAPDHP48, AC010907.1, DCDC2C, LINC01304, AC012445.1, NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1.
- chr2:138,897,151–200,963,680, 811 genes, copy number 7–8 (broad region; genes not listed).
- chr3:84,958,989–99,018,562, 122 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:143,855,739–198,222,513, 937 genes, copy number 7 (broad region; genes not listed).
- chr4:3,463,306–8,516,759, 104 genes, copy number 7 (broad region; genes not listed).
- chr4:19,455,418–59,630,324, 482 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:93,070,387–100,107,613, 61 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:110,099,819–111,231,194, 26 genes, copy number 7 (within-gene range 6–7): WASF1, CDC40, METTL24, AL050350.1, DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1, SLC16A10, RNU6-960P.
- chr12:15,911,302–33,576,200, 303 genes, copy number 9–46 (within-gene range 5–46) (broad region; genes not listed).
- chr13:21,483,834–24,755,201, 68 genes, copy number 14 (broad region; genes not listed).
- chr15:82,647,770–101,933,350, 471 genes, copy number 7 (broad region; genes not listed).
- chr17:58,192,726–61,392,838, 115 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:9,986,126–13,996,443, 55 genes, copy number 7 (within-gene range 6–7): ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,547,623, 7 genes, copy number 7: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2.
- chr20:20,970,448–43,189,970, 499 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:57,895,394–64,313,132, 210 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
